CCDI case PBBPWD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and ill-defined sites within respiratory system and intrathoracic organs.
https://portal.gdc.cancer.gov/cases/bc2af187-903e-4011-a82a-868b8262fa2b

Demographics
Sex at birth: female; Vital status: Alive.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Overlapping lesion of respiratory system and intrathoracic organs; Age at diagnosis: 15.0 years (5,463 days).

Biospecimens (3 samples)
- Sample 0DEV2B: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DEV3D: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DEV4S: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
